Somatic mutation profile of tumor specimen 1105250 (aliquot 7316UP-293-1105250) from CPTAC case C259161, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gliosarcoma; Tissue or organ of origin: Brain, NOS; Tumor grade: G4.
Specimen 1105250: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f94ac77-c563-44d7-9fa1-87de3e317cba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105283 (Blood Derived Normal), aliquot 7316UP-293-1105283; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63365105-9380-4a81-9489-eb78897f63e1

The open-access MAF lists 75 somatic variants for this specimen: 51 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 16, Nonsense Mutation 4, Intron 4, RNA 2, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 12/115 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 106/765 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CDC14C | c.1125A>T p.R375S (on ENST00000428251; = p.R268S on NM_152627.3) | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as rs755866926; called by muse, mutect2
- CDH18 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1434063547, COSV56927210, COSV99931214; called by muse, mutect2
- CFAP206 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.022); catalogued as rs377549577, COSV51535435; called by muse, mutect2, varscan2
- CR2 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 18/323 reads (6%) | catalogued as rs1161576814, COSV65510786; called by muse, mutect2
- EPHA8 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1394031937, COSV51263170; called by muse, mutect2, varscan2
- FARSA | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 20/305 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs868440760; called by muse, mutect2
- HOXB5 | c.662G>T p.R221L | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53313881; called by muse, mutect2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2
- MMP13 | c.1325A>G p.Y442C | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781952022; called by muse, mutect2
- OR14J1 | c.605C>A p.T202K | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.782); catalogued as rs1437616753; called by muse, mutect2
- PLCB4 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 27/384 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.854); catalogued as rs144345083; ClinVar: benign; called by muse, mutect2
- PROP1 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 125/738 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs372313496; called by muse, mutect2, varscan2
- SCN3A | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 14/312 reads (4%) | catalogued as COSV51820116; called by muse, mutect2
- SCN7A | c.1496A>G p.H499R | Missense Mutation (SNP) | VAF 9/193 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.058); catalogued as rs959540957; called by muse, mutect2
- SPAM1 | c.101T>C p.L34S | Missense Mutation (SNP) | VAF 13/205 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.132); catalogued as rs1258146565; called by muse, mutect2
- TAF2 | c.1157T>C p.F386S | Missense Mutation (SNP) | VAF 31/436 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754007710; called by muse, mutect2
- TBX3 | c.806G>A p.R269Q (on ENST00000257566 / NM_016569.4; = p.R249Q on NM_005996.4) | Missense Mutation (SNP) | VAF 39/547 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs775378442, COSV57469287; called by muse, mutect2
- ZNF230 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV71273615; called by muse, mutect2
- ACBD4 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2
- ADAM11 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- ARAP2 | c.624G>C p.K208N | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ARHGEF33 | c.2098G>C p.G700R | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- C2orf81 | c.1552A>G p.T518A | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- CADM3 | c.340A>T p.T114S (on ENST00000368125 / NM_001127173.3; = p.T148S on NM_021189.5) | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDX3X | c.839A>T p.Q280L (on ENST00000399959; = p.Q281L on NM_001356.5) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DLGAP1 | c.870G>T p.E290D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2
- DOCK8 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 48/298 reads (16%) | called by muse, varscan2
- DOCK8 | c.2102C>G p.S701C | Missense Mutation (SNP) | VAF 46/382 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- DOCK8 | c.2413C>T p.Q805* | Nonsense Mutation (SNP) | VAF 35/246 reads (14%) | called by muse, mutect2, varscan2
- FLNB | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.054); called by muse, mutect2
- G3BP2 | c.1294C>G p.R432G | Missense Mutation (SNP) | VAF 20/598 reads (3%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); called by muse, mutect2
- GALNT18 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.829); called by muse, mutect2
- HOXA3 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- IL1RAPL2 | c.900A>T p.I300= | Splice Region (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- ITGA11 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.636); called by muse, mutect2
- ITGA6 | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 37/642 reads (6%) | SIFT tolerated (0.79); PolyPhen probably damaging (1); called by muse, mutect2
- KIF18A | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- NOTCH4 | c.3328T>A p.F1110I | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PDLIM3 | c.8A>C p.Q3P | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2
- PLP2 | c.32G>C p.G11A | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RASGRP4 | c.395A>T p.H132L | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- SLC7A14 | c.2186T>C p.F729S | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- TCTN2 | c.280G>A p.V94M | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- TENM4 | c.8177A>T p.Q2726L | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- TMEM181 | c.518T>G p.I173S | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TMEM187 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TNFRSF11A | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- TPBG | c.1070T>A p.V357D | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- UGT3A2 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2
- CDH1 | c.1095C>G p.V365= | Silent (SNP) | VAF 42/640 reads (7%) | called by muse, mutect2
- CEACAM5 | c.1827G>A p.A609= | Silent (SNP) | VAF 27/363 reads (7%) | catalogued as rs782555811, COSV55752088; called by muse, mutect2
- FOXL2 | c.648C>G p.A216= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- GRIA1 | c.2079A>G p.P693= | Silent (SNP) | VAF 20/233 reads (9%) | called by muse, mutect2
- GRIP2 | c.879C>T p.G293= (on ENST00000619221; = p.G196= on NM_001080423.4) | Silent (SNP) | VAF 13/222 reads (6%) | catalogued as rs774000698, COSV56121182; called by muse, mutect2
- KTN1 | c.3636A>G p.E1212= (on ENST00000395314 / NM_001271014.2; = p.E1183= on NM_004986.4) | Silent (SNP) | VAF 9/135 reads (7%) | called by muse, mutect2
- MMP10 | c.1176T>C p.S392= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- NECAB2 | c.501C>T p.R167= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as rs755827646, COSV100534184; called by muse, mutect2
- PCDHB12 | c.1398C>A p.P466= | Silent (SNP) | VAF 64/870 reads (7%) | catalogued as COSV53398333; called by muse, mutect2
- RAG1 | c.2865C>T p.S955= | Silent (SNP) | VAF 36/532 reads (7%) | catalogued as COSV55025939; called by muse, mutect2
- SALL1 | c.1665C>T p.V555= | Silent (SNP) | VAF 11/137 reads (8%) | catalogued as rs201565524, COSV51757309; called by muse, mutect2
- SDC4 | c.27G>T p.L9= | Silent (SNP) | VAF 23/255 reads (9%) | called by muse, mutect2
- SLC25A22 | c.732C>T p.N244= | Silent (SNP) | VAF 52/697 reads (7%) | called by muse, mutect2
- STK10 | c.2244G>A p.E748= | Silent (SNP) | VAF 25/336 reads (7%) | called by muse, mutect2
- TNF | c.342C>T p.A114= | Silent (SNP) | VAF 9/241 reads (4%) | called by muse, mutect2
- ZNF285 | c.1050G>A p.G350= | Silent (SNP) | VAF 21/260 reads (8%) | catalogued as rs1417500744; called by muse, mutect2
- AC073348.1 | n.171T>A | RNA (SNP) | VAF 13/223 reads (6%) | called by muse, mutect2
- F13A1 | c.1113-9236G>A | Intron (SNP) | VAF 20/240 reads (8%) | catalogued as rs375862509; called by muse, mutect2
- GALM | c.346-1214G>A | Intron (SNP) | VAF 9/214 reads (4%) | called by muse, mutect2
- MS4A2 | c.538-48C>T | Intron (SNP) | VAF 20/250 reads (8%) | catalogued as rs751308080, COSV54012029; called by muse, mutect2
- RMDN1 | chr8:86470298 G>C | 3'Flank (SNP) | VAF 8/277 reads (3%) | called by muse, mutect2
- RMDN1 | chr8:86470299 G>T | 3'Flank (SNP) | VAF 8/280 reads (3%) | called by muse, mutect2
- ROGDI | c.117+238G>A | Intron (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- UGT2B27P | n.1491G>T | RNA (SNP) | VAF 36/486 reads (7%) | called by muse, mutect2
